TCGA case TCGA-DC-6158 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0011a67b-1ba9-4a32-a6b8-7850759a38cf

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 334 days.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 70.8 years (25,842 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Circumferential resection margin: 2; Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 212 days; Disease response: Tumor Free.
- Days to follow up: 216 days; Disease response: Tumor Free.
- Days to follow up: 334 days; Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 1.7 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 71.7 kg; Height: 160 cm; BMI: 28.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DC-6158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.3; Shortest dimension: 0.3.
  Slide TCGA-DC-6158-01A-01-BS1: Section location: Bottom; Percent tumor cells: 67; Percent tumor nuclei: 70; Percent normal cells: 8; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-DC-6158-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-DC-6158-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DC-6158-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; CEA level pretreatment: 1.7; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 334 days; disease-specific survival: no event (censored), 334 days; progression-free interval: no event (censored), 334 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DC-6158-01A-11D-1656-01): tumor purity 0.54, ploidy 2.81, whole-genome doublings 1.
